FM case AD7468 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/6aecee0b-56ab-4e3a-b58d-85bc7df3d3c9

Female, 75.6 years: Adenoid cystic carcinoma (ICD-O-3 8200/3); specimen biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
